Surgical pathology report (de-identified scan), TCGA case TCGA-05-4403, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site Indivumed, specimen TCGA-05-4403-01A (Primary Tumor).

Main diagnosis/diagnoses:

Large peripheral bronchopulmonary, histologically mixed, highly mucigenous adenocarcinoma of the right upper lobe of the lung with a markedly predominant bronchiolo-alveolar of mucinous type and a small acinar and solid part, located mainly in S3.

TNM classification pT2 pN0 R0, stage IB

C 34.1 M 8255/3

Comment/supplementary remark:

There is no evidence that the visceral pleura is infiltrated by the carcinoma. The resection margin of bronchus and vessels and all the lymph nodes removed and identified are tumor-free.

Source: NCI Genomic Data Commons file 568bec54-d918-4ba1-af2e-c183a2b37b83 (TCGA-05-4403.96181BB6-7944-4674-83BA-5268EF8B10A5.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).